Gene-level copy-number profile of tumor specimen TCGA-JX-A3PZ-01A from TCGA case TCGA-JX-A3PZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 25.5 years (9,303 days).
Specimen TCGA-JX-A3PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.c8e683bb-a537-4be1-a4b2-08c637caa5fa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JX-A3PZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3031b4ce-2b08-4cc0-aa6b-b88867457b30

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 49; copy number 2: 6,793; copy number 3: 5,870; copy number 4: 44,013; copy number 5: 1,212; copy number 6: 1,344; copy number 7: 325; copy number 9: 12; copy number 11: 3; copy number 12: 2; copy number 13: 99; copy number 16: 65; copy number 47: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JX-A3PZ-01A-11D-A21P-01): tumor purity 0.7, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:38,168,451–38,640,148, 1 gene (within-gene range 0–2): BTBD9.
- chr6:38,481,692–39,030,792, 11 genes (within-gene range 0–2): BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 201 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:86,547,078–86,696,311, 3 genes, copy number 11 (within-gene range 4–11): CLCA4, CDCA4P2, CLCA4-AS1.
- chr6:29,993,209–31,764,851, 164 genes, copy number 13–16 (broad region; genes not listed).
- chr6:47,477,243–48,068,689, 12 genes, copy number 9 (within-gene range 2–9): AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4.
- chr11:101,451,564–101,872,562, 1 gene, copy number 47 (within-gene range 6–47): TRPC6.
- chr11:101,584,295–102,470,384, 19 genes, copy number 47 (within-gene range 2–47): AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1.
- chr13:73,399,031–73,408,352, 2 genes, copy number 12: AL162376.1, MARK2P12.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
